Somatic mutation profile of tumor specimen MMRF_1740_1_BM_CD138pos (aliquot MMRF_1740_1_BM_CD138pos_T1_KBS5U_L05548) from MMRF case MMRF_1740, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.0 years (30,671 days).
Specimen MMRF_1740_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e5166b-6cc5-4cd0-9de3-114a9c458620.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1740_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1740_1_PB_WBC_C2_KBS5U_L05570; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5be33bcc-17ca-4cff-a536-c848771d2c84

The open-access MAF lists 140 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 45, Missense Mutation 43, Silent 20, Intron 15, 5'UTR 5, RNA 3, 5'Flank 2, Translation Start Site 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 51/140 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV57123803; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs749374616; called by muse, mutect2
- C8A | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs199713008; called by muse, mutect2, varscan2
- CALD1 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100724611; called by muse, mutect2, varscan2
- CDH10 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52598635; called by muse, mutect2, varscan2
- CTU2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1268141366; called by muse, mutect2, varscan2
- DDX20 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 176/399 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV63831018; called by muse, mutect2, varscan2
- EIF4G3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768014443, COSV51691660; called by muse, mutect2, varscan2
- EPPK1 | c.6125C>T p.A2042V | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs375707682; called by muse, mutect2, varscan2
- FAT4 | c.11509G>C p.V3837L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as rs1437496744; called by muse, mutect2, varscan2
- HECTD4 | c.8746G>A p.G2916S | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs267603312; called by muse, mutect2, varscan2
- IGLV3-1 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs189772470; called by muse, varscan2
- IGLV3-1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs185803370; called by muse, varscan2
- INTS14 | c.380G>A p.R127Q (on ENST00000313182 / NM_001366360.2; = p.R48Q on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs749850609; called by muse, mutect2, varscan2
- ITIH2 | c.2780T>C p.I927T | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1367119820; called by muse, mutect2, varscan2
- MED25 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs764017333; called by muse, mutect2
- NUP88 | c.2213A>G p.H738R | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs752602041; called by muse, mutect2, varscan2
- OBSCN | c.14233C>T p.R4745W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs570545660, COSV99476706; called by muse, mutect2, varscan2
- OR52E4 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1026499650; called by muse, mutect2, varscan2
- PLCL1 | c.545A>C p.D182A | Missense Mutation (SNP) | VAF 114/284 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as COSV101407356; called by muse, mutect2, varscan2
- RBL2 | c.2396T>C p.L799S | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.138); catalogued as rs1202855248; called by muse, mutect2, varscan2
- SPEG | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as rs546717275; called by muse, mutect2, varscan2
- SVIL | c.6296C>T p.P2099L (on ENST00000355867 / NM_021738.3; = p.P1673L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1218163256; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998709072; called by muse, mutect2, varscan2
- ABCC9 | c.3827T>A p.M1276K | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ABHD1 | c.458A>C p.Q153P | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- C2 | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- CCDC112 | c.1289T>C p.I430T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- CTDSPL2 | c.692-1G>A p.X231_splice | Splice Site (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- DDX58 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIP2B | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DYNC2H1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- DYRK1A | c.2238_2239insTA p.E747* | Frame Shift Ins (INS) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- ELF1 | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2
- IGLV8-61 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KRT23 | c.1084A>C p.T362P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- LRBA | c.1602+1del p.X534_splice | Splice Site (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- LRRC66 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NOC2L | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2
- NR3C2 | c.1966C>G p.P656A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR8U1 | c.232A>C p.T78P | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PRKCG | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2
- THSD7B | c.4796C>G p.T1599S (on ENST00000272643; = p.T1597S on NM_001316349.2) | Missense Mutation (SNP) | VAF 17/587 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMA7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- UNC5C | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- XIRP2 | c.7892A>G p.E2631G (on ENST00000628543; = p.E2806G on NM_152381.6) | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- ZBED1 | c.1854del p.E619Sfs*97 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- ZNF844 | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ACTG1 | c.51C>T p.C17= | Silent (SNP) | VAF 109/285 reads (38%) | catalogued as rs201570725, COSV59512020; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCND1 | c.138A>G p.K46= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV57120497, COSV57122060; called by muse, mutect2
- CCND1 | c.285A>G p.K95= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as rs760878237; called by muse, mutect2, varscan2
- CELSR2 | c.3924C>T p.G1308= | Silent (SNP) | VAF 69/156 reads (44%) | catalogued as COSV99605127; called by muse, mutect2, varscan2
- CLEC4F | c.6C>T p.D2= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs545217273; called by muse, mutect2, varscan2
- CPLX2 | c.360G>A p.V120= | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as COSV64001862; called by muse, mutect2, varscan2
- DOCK10 | c.1005A>C p.A335= | Silent (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- FAT1 | c.7872T>C p.D2624= | Silent (SNP) | VAF 58/156 reads (37%) | called by muse, mutect2, varscan2
- GCNT4 | c.1215A>G p.G405= | Silent (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- KAT5 | c.525C>T p.A175= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs540553489; called by muse, mutect2, varscan2
- KCTD8 | c.546G>A p.A182= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, varscan2
- MAFB | c.936C>T p.T312= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- MUCL3 | c.1239A>G p.S413= (on ENST00000304311; = p.S1289= on NM_080870.4) | Silent (SNP) | VAF 48/170 reads (28%) | called by muse, mutect2, varscan2
- NR5A1 | c.666C>T p.N222= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs558743021, CD091586, COSV101007668; called by muse, mutect2, varscan2
- NUP98 | c.2433G>A p.V811= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1469516142; called by muse, mutect2
- SEC61A2 | c.807G>T p.S269= | Silent (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
- SLC1A5 | c.1062C>T p.S354= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs561516574; called by muse, mutect2, varscan2
- TOLLIP | c.516C>T p.Y172= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs774633513; called by muse, mutect2, varscan2
- ZBTB40 | c.183C>T p.I61= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs770873034; called by muse, mutect2, varscan2
- ZBTB45 | c.1395C>T p.A465= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs1459951725; called by muse, mutect2, varscan2
- AC018563.1 | n.396A>G | RNA (SNP) | VAF 8/64 reads (13%) | catalogued as rs1311547827; called by muse, mutect2, varscan2
- ADAMTS12 | c.*466T>A | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*592A>G | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- ADARB2 | c.*692G>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs1487593150; called by muse, varscan2
- ANTXR2 | c.*2570dup | 3'UTR (INS) | VAF 48/104 reads (46%) | catalogued as rs987611494; called by mutect2, varscan2
- BHLHE40 | c.*1038G>T | 3'UTR (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- BRAF | c.241-13C>A | Intron (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- BTBD3 | c.*145T>G | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- C5orf64 | n.513-43351C>T | Intron (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- CCDC39 | c.2159-28T>C | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CCSER1 | c.*211C>T | 3'UTR (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- CEP85L | c.*1383A>C | 3'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- CHD8 | c.844-187C>T | Intron (SNP) | VAF 10/18 reads (56%) | catalogued as rs950247325; called by muse, mutect2, varscan2
- DBNL | c.*4679T>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- DCC | c.*2874A>T | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- EDIL3 | c.*566A>T | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- EFNA3 | c.-41C>T | 5'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- EPHA3 | c.1594+338C>A | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- EPN2 | c.*1272A>T | 3'UTR (SNP) | VAF 149/350 reads (43%) | called by muse, mutect2, varscan2
- ESRRB | c.*137G>A | 3'UTR (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- FAT1 | c.*129C>A | 3'UTR (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- FAT3 | c.*4142T>A | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- FBN2 | c.-579G>A | 5'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2072A>G | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- GCFC2 | c.1226+32C>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- HNRNPU | c.*618_*621del | 3'UTR (DEL) | VAF 37/160 reads (23%) | catalogued as rs549025539; called by mutect2, pindel, varscan2
- INA | c.*612C>T | 3'UTR (SNP) | VAF 4/64 reads (6%) | catalogued as rs948055186; called by muse, mutect2
- IQCJ | c.291+377G>T | Intron (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- KCNAB2 | c.502+815G>C | Intron (SNP) | VAF 8/69 reads (12%) | catalogued as rs957677994; called by muse, mutect2, varscan2
- KCTD10 | c.387+1073G>A | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as rs1258528905; called by muse, mutect2, varscan2
- KCTD12 | c.*3324A>C | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- KIF1A | c.*3031C>T | 3'UTR (SNP) | VAF 63/174 reads (36%) | called by muse, mutect2, varscan2
- KLHL4 | c.*3334T>C | 3'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851154 T>A | 5'Flank (SNP) | VAF 76/211 reads (36%) | catalogued as rs773647840; called by muse, varscan2
- MLLT11 | c.*517G>A | 3'UTR (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- MLPH | c.1777-375G>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- NANOGP1 | n.1445del | RNA (DEL) | VAF 35/108 reads (32%) | catalogued as rs1565597063; called by mutect2, pindel, varscan2
- NFU1 | chr2:69437568 C>T | 5'Flank (SNP) | VAF 55/133 reads (41%) | called by muse, mutect2, varscan2
- NOVA1 | c.*332G>T | 3'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- NR3C2 | c.*152C>T | 3'UTR (SNP) | VAF 10/154 reads (6%) | catalogued as rs1016440477; called by muse, mutect2
- NR5A2 | c.*1488C>T | 3'UTR (SNP) | VAF 61/111 reads (55%) | called by muse, mutect2, varscan2
- NRXN3 | c.*194C>A | 3'UTR (SNP) | VAF 34/92 reads (37%) | called by muse, varscan2
- NUDT5 | c.*922C>G | 3'UTR (SNP) | VAF 118/270 reads (44%) | called by muse, mutect2, varscan2
- PARD6B | c.*3160A>T | 3'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as COSV65405208; called by muse, mutect2, varscan2
- PHF19 | c.*743T>C | 3'UTR (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- PLA2G4D | c.*976A>G | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- PLCL2 | c.3019-90A>C | Intron (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- POU3F4 | c.*270T>C | 3'UTR (SNP) | VAF 28/31 reads (90%) | catalogued as COSV64538033; called by muse, mutect2, varscan2
- PRKAB2 | c.*3484G>A | 3'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.392+1141T>A | Intron (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- PTPRF | c.*867A>C | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- RBM46 | c.*207G>A | 3'UTR (SNP) | VAF 50/131 reads (38%) | called by muse, mutect2, varscan2
- RBM5 | c.-42T>A | 5'UTR (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- RHOT2 | c.869+65C>T | Intron (SNP) | VAF 87/260 reads (33%) | called by muse, mutect2, varscan2
- RNF125 | c.*945A>T | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- RNF185 | c.*565T>A | 3'UTR (SNP) | VAF 11/295 reads (4%) | catalogued as COSV99839748; called by muse, mutect2
- RNF217 | c.*3025G>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- ROR1 | c.*937A>T | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+729C>T | Intron (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- SKP1P2 | n.166A>T | RNA (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- SLC24A1 | c.*134T>C | 3'UTR (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
- SNPH | c.*1655C>T | 3'UTR (SNP) | VAF 135/322 reads (42%) | catalogued as COSV100378089; called by muse, mutect2, varscan2
- SRGAP1 | c.*2015C>A | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- STK32B | c.*950A>T | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- SURF4 | c.-74C>T | 5'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- TBC1D1 | c.*1085C>T | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- TEX15 | c.-3G>A | 5'UTR (SNP) | VAF 7/144 reads (5%) | catalogued as rs1480144921; called by muse, mutect2
- THBD | c.*1462T>C | 3'UTR (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- TRIM7 | c.619-686dup | Intron (INS) | VAF 36/89 reads (40%) | catalogued as rs1364658813; called by mutect2, pindel, varscan2
- WDR72 | c.*987dup | 3'UTR (INS) | VAF 21/62 reads (34%) | catalogued as rs1165409876; called by mutect2, pindel, varscan2
